TCGA case TCGA-XF-AAN0 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e7e95597-ef88-4442-8c01-8d633822e7b5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 1,718 days (4.7 years).

Diagnoses (2)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 68.1 years (24,877 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T4a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension: Focal; Extracapsular extension present: Yes; Lymph nodes positive: 30; Lymph nodes tested: 53; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 53 days; Days to treatment end: 53 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride + Paclitaxel; Days to treatment start: 53 days; Days to treatment end: 175 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Halichondrin B; Days to treatment start: 614 days (1.7 years); Days to treatment end: 866 days (2.4 years); Treatment outcome: Partial Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Ifosfamide + Paclitaxel; Days to treatment start: 898 days (2.5 years); Days to treatment end: 1,052 days (2.9 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride + Gemcitabine; Days to treatment start: 1,094 days (3.0 years); Days to treatment end: 1,136 days (3.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride + Gemcitabine; Days to treatment start: 1,265 days (3.5 years); Days to treatment end: 1,318 days (3.6 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 1,423 days (3.9 years); Days to treatment end: 1,486 days (4.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Days to treatment start: 1,465 days (4.0 years); Days to treatment end: 1,486 days (4.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride + Gemcitabine; Days to treatment start: 1,598 days (4.4 years); Days to treatment end: 1,598 days (4.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temsirolimus + Vinorelbine; Days to treatment start: 1,703 days (4.7 years); Days to treatment end: 1,703 days (4.7 years); Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Scrotum, NOS. Age at diagnosis: 69.8 years (25,480 days); Days to diagnosis: 603 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 702 days (1.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 603 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Scrotum, NOS; Days to recurrence: 603 days (1.7 years).
- Days to follow up: 1,718 days (4.7 years); Disease response: With Tumor.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 172 cm; BMI: 25.4.

Exposures
- Occupation type: Business Services and Administration Managers.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 56; Tobacco smoking quit year: 1982; Age at onset: 17.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-AAN0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 690 mg.
  Slide TCGA-XF-AAN0-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
- Sample TCGA-XF-AAN0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-AAN0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Retired; Occupation primary: financial manager; Occupation primary industry: Music Industry; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response.
- Metastatic site list: Metastasis site: Lymph node only.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Pacitaxol.
- Drug treatment 3: Pharmaceutical therapy drug name: Gemzar.
- Drug treatment 4: Pharmaceutical therapy drug name: Halichondrin; Clinical trial drug classification: Anti-tubulin agent.
- Drug treatment 6: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 8: Pharmaceutical therapy drug name: Adriamycin (doxorubicin).
- Drug treatment 14: Treatment best response: Clinical Progressive Disease.
- Drug treatment 15: Pharmaceutical therapy drug name: Adriamycin (doxorubicin); Treatment best response: Clinical Progressive Disease.
- Drug treatment 16: Clinical trial drug classification: mTOR inhibitor.
- Drug treatment 17: Clinical trial drug classification: anti-mitotic, vinca alkaloid.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,718 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,718 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 603 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-AAN0-01A-11D-A42D-01): tumor purity 0.52, ploidy 3.66, whole-genome doublings 1.
